Somatic mutation profile of tumor specimen 0DWD29 from CCDI case PBCMTN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,392 days).
Specimen 0DWD29: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20d924f3-e90f-4043-be4d-fff1c08ebdac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e8a0bf9-899a-4430-96e5-0525abc4fad6

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 1, Nonsense Mutation 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRCAP | c.6985C>T p.R2329* | Nonsense Mutation (SNP) | VAF 46/796 reads (6%) | catalogued as rs1555465891, CM1411785, COSV52682925; ClinVar: likely pathogenic; called by muse, mutect2
- CCDC9B | c.23G>C p.R8P | Missense Mutation (SNP) | VAF 44/717 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- KDM6A | c.3210-7_3210-4del | Splice Region (DEL) | VAF 428/458 reads (93%) | called by mutect2, pindel, varscan2
- PRKCG | c.426T>C p.C142= | Silent (SNP) | VAF 17/340 reads (5%) | catalogued as COSV54724604; called by muse, mutect2
- SATB2 | c.1209C>T p.D403= | Silent (SNP) | VAF 63/928 reads (7%) | catalogued as COSV53493882; called by muse, mutect2
- TTPAL | c.861C>T p.N287= | Silent (SNP) | VAF 50/758 reads (7%) | catalogued as rs180792442, COSV99375282; called by muse, mutect2
- PFKL | c.86-819C>T | Intron (SNP) | VAF 136/690 reads (20%) | called by mutect2, varscan2
